Somatic mutation profile of tumor specimen MP2PRT-PAUKXG-TMP1-A (aliquot MP2PRT-PAUKXG-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUKXG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.4 years (1,243 days).
Specimen MP2PRT-PAUKXG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3519d3f-a705-4667-9781-e487331a2cc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKXG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKXG-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8164650d-53a2-433e-9516-709017bd1d73

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNTL2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758271274, COSV53824759; called by muse, mutect2, varscan2
- DSG1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754601260; called by muse, mutect2, varscan2
- FCSK | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs767472330, COSV99850546; called by muse, mutect2, varscan2
- KMT2D | c.8971C>G p.P2991A | Missense Mutation (SNP) | VAF 169/402 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs754421145; called by muse, mutect2, varscan2
- MYH6 | c.4648G>C p.E1550Q | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100676308; called by muse, mutect2, varscan2
- NLRP11 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs769380246; called by muse, mutect2, varscan2
- PCDHA13 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 222/542 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs781822448; called by muse, mutect2, varscan2
- SYNPO | c.2110C>T p.R704C (on ENST00000394243 / NM_001166208.2; = p.R460C on NM_007286.6) | Missense Mutation (SNP) | VAF 203/530 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs755694682, COSV56940059; called by muse, mutect2, varscan2
- ALG5 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARNT2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DBX2 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 109/345 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GBP5 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP214 | c.3790T>A p.S1264T | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SCRIB | c.4711G>A p.E1571K | Missense Mutation (SNP) | VAF 196/529 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- WDR59 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KDM4F | c.1095G>A p.R365= | Silent (SNP) | VAF 45/290 reads (16%) | catalogued as rs899350840; called by muse, mutect2, varscan2
- VCAN | c.354C>A p.V118= | Silent (SNP) | VAF 144/369 reads (39%) | catalogued as COSV99425766; called by muse, mutect2
